Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5989, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5989-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGIC DIAGNOSIS:

A. RIGHT KIDNEY, REDICAL NEPHRECTOMY

RENAL CELL CARCINOMA, clear cell type, Fuhrman nuclear grade II/IV (9.0 cm).

Tumor is located in the upper pole and limited to kidney.

No lymphovascular invasion is present.

The vascular and ureteral margins are negative for tumor.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

B. RIGHT REGIONAL NODES:

One (1) lymph node, negative for tumor.

AJCC Classification (6th Edition): T2 No Mx

CLINICAL DATA:

History: None given.

Operation: Right radical nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1. Right kidney [REDACTED]

B/2. Right regional nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "#1. Rt kidney", consists of a 549 gram radical nephrectomy specimen, comprised of right kidney (15.0 x 8.5 x 8.0 cm), with contiguous 7.0 cm ureter (diameter is 0.7 cm), 2.1 cm renal artery (diameter 0.6 cm), and 1.2 cm renal vein (diameter 1.8 cm). Specimen has been previously inked and sectioned, revealing a 9.0 x 8.0 x 8.0 cm well-circumscribed tan/yellow to tan/red irregular, encapsulated mass, which is located in the upper pole and abuts the renal capsule as well as the inked surgical margin. Mass is 11.2 cm from the ureteral margin, 2.8 cm from the renal artery margin and 0.6 cm from the renal vein margin. Representative mass has been previously sent for cytogenetics, quick fix and tissue bank. Representative normal renal parenchyma has been sent to tissue bank, EM, IF. Mass occupies at least 60% of the renal parenchyma, the remaining of which is unremarkable. Corticomedullary junctions are distinct. Urothelium is tan/white and unremarkable. Gerota's fascia is not seen grossly. Adrenal gland is not identified within the specimen.

Micro A1: Artery, ureter, vein margins, 3 frags, [REDACTED]
Micro A2: Tumor, quick fix section, 1 frag, [REDACTED]
Micro A3-A4: Tumor and renal capsule, black - inked margin, 4 frags
total, [REDACTED]
Micro A5: Tumor and adjacent renal vein, 2 frags, RSS.
Micro A6: Tumor with respect to uninvolved renal parenchyma, 1 frag,
RSS.
Micro A7: Uninvolved renal parenchyma, 1 frag, [REDACTED]

Part B, "#2. Rt regional lymph node", consists of 1.4 cm lymph node, bisected

[page 2 of 4]
ADDENDUM #1

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA (SEE NOTE)

ARTERIAL AND ARTERIOLAR SCLEROSIS, MILD (SEE NOTE)

NOTE:

The kidney parenchyma shows minimal chronic changes, within the expected range for a sixty year-old man. There is isolated focal global glomerulosclerosis (0.77% of glomeruli) and minimal tubular atrophy and interstitial fibrosis (less than 5% of the parenchyma). The arteries and arterioles show a mild degree of vascular sclerosis.

Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A7) were evaluated using H&E, PAS, silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 129 glomeruli present, of which one (0.77%) is globally sclerosed. The glomeruli show no significant pathologic changes. There are only isolated irregularities of the glomerular capillary wall basement membranes. Rare distal tubules contain PAS-positive hyaline casts. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a mild degree of subintimal sclerosis.

[page 3 of 4]
KARYOTYPE: 46,XY,ins(2;3)(q33;p13p23)[5]

METAPHASES COUNTED: 5 ANALYZED: 5 SCORED: 0 BANDING: GTG

INTERPRETATION:

All five metaphases contained an insertion between chromosomes 2 and 3.
Rearrangements involving chromosome 3p are common findings in clear cell carcinoma.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC; Kidney tumor

[page 4 of 4]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c7464a5a-c20f-4f1f-90b7-6fdf6ef6eaeb (TCGA-CZ-5989.9FA904A6-4377-4FAA-82B0-F0B313602C42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).